Surgical pathology report (de-identified scan), TCGA case TCGA-XK-AAK1, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site Mayo Clinic Arizona, specimen TCGA-XK-AAK1-01A (Primary Tumor).

[page 1 of 4]
Surgical Pathology Report

****ADDENDUM PRESENT****

Patient Name: [REDACTED]
Clinic Number: [REDACTED]
Date of Birth: (Age: Gender: M)
Requested By:

Accession #:
Procedure Date:
Received Date:
Account #:
Report Signed:

Final Diagnosis:

Prostate with bilateral lymph nodes, radical prostatectomy: Prostatic adenocarcinoma (Gleason score 4+3=7), bilateral.

Procedure: Radical prostatectomy with bilateral lymph node dissection.

Histologic type: Prostatic adenocarcinoma, acinar type.

Histologic grade:

Primary pattern: 4, Secondary pattern: 3, Tertiary pattern: Not applicable.

Total Gleason Score: 7

Tumor quantitation and location: Bilateral. The predominant tumor is identified in the apex and midportion of the left lobe, measuring up to 14 mm in greatest dimension (microscopic measurement). Scattered smaller foci of prostatic adenocarcinoma (measuring up to 7 mm) are identified in the left base, right apex, right mid, and right base.

Extraprostatic extension: Not identified

Margins: Negative for malignancy.

Lymph-vascular invasion: Not identified.

Perineural invasion: Not identified.

Seminal vesicle invasion: Not identified.

Treatment effect on carcinoma: Not applicable.

Lymph nodes: Six lymph nodes, negative for malignancy (0/6).

Additional pathologic findings: None.

Prostate weight: 35 g.

Prostate size: 40 x 40 x 30 mm.

Ancillary studies: DNA ploidy will be performed and results REPORTED IN AN ADDENDUM.

Pathologic staging (AJCC 2010): T2c.

Biorepository sample: Contains carcinoma.

Block(s) containing malignancy suitable for additional testing: A3, A7, A8, A9, A13.

ICD-O-3
Adenocarcinoma NOS 8140/3
Site Prostate NOS 061.9
JW 3/25/14

Interpreted by:

Report electronically signed out by

Transcribed by

ADDENDA:

Paraffin embedded tissue (Block A7) was forwarded to

[page 2 of 4]
for DNA Ploidy by DIA testing. This report follows:

interpreted by

Source: Prostate, radical prostatectomy, block.

The cancer cells are DNA diploid.

DIA ploidy test results have been validated by our laboratory for formalin-fixed, paraffin embedded tissue sections. Analysis was performed using the instrument (operator) which determined DNA ploidy status by comparing the DNA content of tumor cells and control cells (selected by operator).
Laboratory Developed Test

Proliferation index Ki-67 (MIB-1) = 2.36%.

Method: Immunohistochemical staining of the Ki-67 antigen in formalin-fixed paraffin-embedded tissue sections has been validated by our laboratory, using the MIB-1 clone and a proprietary detection system. All controls show appropriate reactivity. Image collection and analysis is performed using the instrument. The renders the percentage of positive staining tumor nuclei (tumor selected by operator).
Laboratory Developed Test

Transcribed by

Signed by

Clinical Information:

Prostate CA.

Specimen(s):

A: Prostate with bilateral lymph nodes

Gross Description:

Performed by

A1A2A3A4A5A6A7A8A9A10A11A12A13A14A15A16A17A18A19A20

A. The specimen is received fresh labeled [redacted] and "prostate and bilateral pelvic lymph nodes".

Weight: 35 g.

Dimensions: 4.0 x 4.0 x 3.0 cm.

Seminal vesicles: Right--3.0 x 1.5 x 0.5 cm and left--3.5 x 1.5 x 0.6 cm.

Grossly evident tumor: None.

Gross capsular bulge/defect: None.

Symmetry: Symmetrical.

Gross nodular hyperplasia: Mild to moderate.

Lymph Nodes: There is a 6.0 x 5.0 x 1.5 cm collection of rubbery and fatty tissue which appears to represent the bilateral pelvic lymph nodes. This tissue is sectioned to reveal several rubbery and fatty lymph nodes measuring up to 3.0 cm in greatest dimension.

Inking Details: Left - black and right - blue

Biorepository sample collected: Yes, see block key.

[page 3 of 4]
Block Summary for Specimen A:

- 1) proximal urethral margin
- 2) distal urethral margin
- 3) left apical margin
- 4) right apical margin
- 5) left bladder neck margin
- 6) right bladder neck margin
- 7) left apical prostate
- 8) right apical prostate
- 9) left mid prostate
- 10) right mid prostate
- 11) left mid prostate
- 12) right mid prostate
- 13) left base of prostate
- 14) right base of prostate
- 15) left seminal vesicle with junction of prostate
- 16) right seminal vesicle with junction of prostate
- 17) mirror image of tissue submitted for
- 18) one lymph node, bisected.
- 19) one lymph node, bisected.
- 20) four whole lymph nodes.

*Pw TSS dx discrepancy form,
TCGA tumor is Gleason 4+4.*

in this case may have included the use of immunohistochemistry tests that were developed and whose performance characteristics were determined by
They have not been cleared or approved by the U. S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is
not necessary. These tests should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA) as
qualified to perform high complexity clinical laboratory testing

END OF REPORT

Page 3 of 3

[page 4 of 4]
TCGA Pathologic Diagnosis Discrepancy Form

V4.00

Instructions: The TCGA Pathologic Diagnosis Discrepancy Form should be completed when the pathologic diagnosis documented on the initial pathology report for a case submitted for TCGA is inconsistent with the diagnosis provided on the Case Quality Control Form completed for the submitted case.

Tissue Source Site (TSS): _____ TSS Identifier: _____ TSS Unique Patient Identifier: _____

Completed By (Interviewer Name on OpenClinica): _____ Completed Date: _____

Diagnosis Information

#	Data Element	Entry Alternatives	Working Instructions
1	Pathologic Diagnosis Provided on Initial Pathology Report	Prostatic adenocarcinoma acinar type Gleason 4+3 = 7	Provide the diagnosis/ histologic subtype(s) documented on the initial pathology report for this case. If the histology for this case is mixed, provide all listed subtypes.
2	Histologic features of the sample provided for TCGA, as reflected on the CQCF.	Prostatic adenocarcinoma, acinar type Gleason 4+4 = 8	Provide the histologic features selected on the TCGA Case Quality Control Form completed for this case.

Discrepancy between Pathology Report and Case Quality Control Form

3	Provide the reason for the discrepancy between the pathology report and the TCGA Case Quality Control Form.	Gleason on path report is 4+3 = 7. Gleason on sample sent to TCGA is higher at 4+4 = 8.	Provide a reason describing why the diagnosis on the initial pathology report for this case is not consistent with the diagnosis selected on the TCGA Case Quality Control Form.
4	Name of TSS Reviewing Pathologist or Biorepository Director		Provide the name of the pathologist who reviewed this case for TCGA.

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled.

TSS Reviewing Pathologist or Biorepository Director

Date

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled. The Attending Pathologist or the Department Chairman has been informed or is aware of the above discrepancy in diagnoses.

Investigator Signature

Date

Source: NCI Genomic Data Commons file 9c4bec7c-5d67-4ada-b2a6-6df8401faa81 (TCGA-XK-AAK1.55565AD3-723E-4899-BBEA-D6FDF557E4C6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).